Somatic mutation profile of tumor specimen ALCH-B4QD-TTP1-A (aliquot ALCH-B4QD-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4QD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.1 years (28,531 days).
Specimen ALCH-B4QD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aeaa80ae-71f7-4dee-bef5-efd8721a4a55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4QD-NB1-A (Blood Derived Normal), aliquot ALCH-B4QD-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/011578fd-fe51-42fc-a931-15c493e5535b

The open-access MAF lists 37 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 5, In Frame Del 1, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NT5C2 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as rs769873284; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 167/620 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs61751418, CM094933; called by muse, mutect2, varscan2
- ITFG1 | c.1606A>G p.I536V | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs763027424; called by muse, mutect2, varscan2
- ITIH6 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs372063113; called by muse, mutect2, varscan2
- KNG1 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs377332435; called by muse, mutect2
- MYH13 | c.5376G>C p.Q1792H | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs933042834; called by muse, mutect2, varscan2
- ABCA8 | c.3224C>G p.S1075C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ACTR1B | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2
- AMOTL1 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 155/651 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFIP2 | c.821del p.K274Sfs*20 | Frame Shift Del (DEL) | VAF 50/248 reads (20%) | called by mutect2, pindel, varscan2
- ARHGEF4 | c.1107A>C p.Q369H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- CEBPZ | c.1608_1616del p.Q537_T539del | In Frame Del (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- CYB561 | c.149T>G p.F50C | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DERL2 | c.694G>C p.G232R | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- KRTAP27-1 | c.215A>T p.D72V | Missense Mutation (SNP) | VAF 89/516 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LILRA5 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NXPE4 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEC24D | c.1197C>G p.F399L | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SUDS3 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- TMEM132D | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ZNF345 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FBXO41 | c.975G>C p.L325= | Silent (SNP) | VAF 63/283 reads (22%) | called by muse, mutect2, varscan2
- MAMDC2 | c.12G>A p.R4= | Silent (SNP) | VAF 10/266 reads (4%) | catalogued as rs938522077, COSV65857431; called by muse, mutect2
- PCDHGA1 | c.438G>A p.T146= | Silent (SNP) | VAF 69/328 reads (21%) | called by muse, mutect2, varscan2
- RBM3 | c.345C>A p.G115= | Silent (SNP) | VAF 51/343 reads (15%) | called by muse, mutect2, varscan2
- RNF8 | c.1048C>T p.L350= | Silent (SNP) | VAF 59/166 reads (36%) | called by muse, mutect2, varscan2
- SECISBP2L | c.3294G>A p.T1098= (on ENST00000559471 / NM_001193489.2; = p.T1053= on NM_014701.4) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs199982398, COSV99961105; called by muse, varscan2
- TENT5B | c.258C>A p.I86= | Silent (SNP) | VAF 122/410 reads (30%) | catalogued as rs570359008, COSV56694101; called by muse, mutect2, varscan2
- TMEM132D | c.2445G>T p.G815= | Silent (SNP) | VAF 86/265 reads (32%) | called by muse, mutect2, varscan2
- UBE2NL | c.285G>A p.K95= | Silent (SNP) | VAF 132/705 reads (19%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39486C>T | Intron (SNP) | VAF 129/383 reads (34%) | called by muse, mutect2, varscan2
- CCDC191 | chr3:114056560 C>T | 5'Flank (SNP) | VAF 72/201 reads (36%) | catalogued as rs750660546, COSV99846847; called by muse, mutect2, varscan2
- CCDC198 | c.656-4018C>T | Intron (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99371104; called by muse, mutect2
- GARS1 | c.222+735G>T | Intron (SNP) | VAF 95/489 reads (19%) | called by muse, mutect2, varscan2
- MORC2 | chr22:30922491 G>A | 3'Flank (SNP) | VAF 88/307 reads (29%) | catalogued as rs1182710060; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-68068G>A | Intron (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- SMARCC1 | c.3043+5751C>A | Intron (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
